Somatic mutation profile of tumor specimen RC-B658-TBP1-A (aliquot RC-B658-TBP1-A-1-0-D-A93N-47) from RC case RC-B658, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Anaplastic large cell lymphoma, ALK negative; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 53.5 years (19,550 days).
Specimen RC-B658-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01c6dc3d-91a8-4d49-b53f-2500e93a2077.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B658-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B658-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/baaaefef-cdb6-49d2-8dac-ab034afb460a

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPN2 | c.1234C>A p.Q412K | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0.015); catalogued as COSV60471136; called by muse, mutect2
- CTSO | c.929G>A p.C310Y | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SRSF3 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
